Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ACQQ, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ACQQ-TTP1-A (Primary Tumor).

[page 1 of 2]
Clinical data and diagnostic questions

Right lung lesion in a patient with interstitial disease and mediastinal neoplasm

Sample sent as:

1. Lymph node n4
2. Lymph node n2
3. Lymph node n8
4. Right upper lung lobe

CDDP-YP-ACQQ-01-PR

Macroscopic report:

1. Anthracotic lymph node of cm 0.5
2. Anthracotic lymph node of cm 0.5
3. Anthracotic lymph node of cm 0.5
4. Pulmonary parenchyma segment measuring cm 3x1.5x1, with metal sutures on the pleural surface that appears smooth. To the cut, close to the resection margin is present a greyish hard area, whit hazy limits of mm 7 of major axis.

Microscopic report:

1. 2.3. Confirming what verbally expressed in the course of extemporaneous examination the definitive histological sections after fixation and inclusion evidence anthracotic lymph nodes and negative for metastatic disease.
4. Nodule macroscopically described championship in totally corresponds to epithelial malignancy with the characters of moderately differentiated infiltrating adenocarcinoma. The tumor is associated with sclerotic and inflamed stroma. Nests of neoplastic elements are also present in scattered alveoli in the surrounding lung parenchyma, this presents bullous emphysema. Free surgical margin.

Findings and histopathological diagnosis

1. 2.3. Anthracotic lymph nodes.
4. Adenocarcinoma infiltrating the lung parenchyma.

ICD-0-3

adenocarcinoma, NOS 8140/3

Site: @lung, upper lobe C34.1

ICD-10

C34.11

hw
12/11/14

[page 2 of 2]
Sample sent as:

1. Lymph node n4
2. Lymph node n2
3. Lymph node n8

Macroscopic report:

1. Anthracotic lymph node of cm 0.5
2. Anthracotic lymph node of cm 0.5
3. Anthracotic lymph node of cm 0.5

Conclusions and diagnosis

1. 2.3. Anthracotic lymph nodes. No evidence of neoplasia (see note)

Note 1: Interim response reported by telephone being extemporaneous examination to
Following the final report of fixed material and included.

Clinical data and diagnostic questions

Right lung neoplasm

Sample sent as:

Right lung. needle aspiration cytology

Macroscopic report:

Examining five crawled slides, and colored with Papanicolau stain.

Microscopic report:

One of the slide for cytology evaluation shows abundant cellularity consists of large size elements with vesicular nucleus, irregular, nucleolar. These elements are arranged in nests, aggregates, arge flaps. It is found naked nuclei.

Cytological finding is neoplastic and indicates carcinoma, adenocarcinoma more likely

Conclusions and diagnosis

Neoplastic cytological finding

Source: NCI Genomic Data Commons file b9e8ca1a-4f2d-496b-aa16-044f16cc5193 (CDDP-ACQQ-TTP1.25EBB72A-A099-4116-BA7A-579C3E005943.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).